Somatic mutation profile of tumor specimen TARGET-10-PASWXB-09A (aliquot TARGET-10-PASWXB-09A-01D) from TARGET case TARGET-10-PASWXB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,526 days).
Specimen TARGET-10-PASWXB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b88ee9e-c3b6-44b3-b061-f69458ff1d8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASWXB-10A (Blood Derived Normal), aliquot TARGET-10-PASWXB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecd08847-4640-491f-9f78-ab69ebfc4123

The open-access MAF lists 28 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 3, Frame Shift Ins 2, 5'UTR 2, 3'UTR 2, Splice Region 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs397507512, CM030494, CM056378, COSV61006422; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCAN | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as rs771345270, COSV61260517; called by muse, mutect2, varscan2
- CASZ1 | c.3035+4A>G | Splice Region (SNP) | VAF 29/58 reads (50%) | catalogued as COSV59742575; called by muse, mutect2, varscan2
- DOCK2 | c.2555-2A>G p.X852_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV56997436; called by muse, mutect2, varscan2
- DRC3 | c.541T>G p.Y181D | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV58267517; called by muse, mutect2
- F7 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs200212201, CM002767, COSV60646513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGB | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs964302458, COSV57417611, COSV57420085; called by muse, mutect2, varscan2
- MMD2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs747236601, COSV68661333; called by muse, mutect2, varscan2
- NOTCH1 | c.7171C>T p.Q2391* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV53033191; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- POM121C | c.1094G>A p.R365K (on ENST00000607367; = p.R123K on NM_001099415.3) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV57550751; called by muse, mutect2, varscan2
- RBX1 | c.308T>C p.F103S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV53429645; called by muse, mutect2, varscan2
- TBX6 | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54223851; called by muse, mutect2, varscan2
- CSDE1 | c.382_383insGTCCTTTG p.V128Gfs*15 | Frame Shift Ins (INS) | VAF 32/80 reads (40%) | called by mutect2, pindel, varscan2
- RNF166 | c.637_638insGGCG p.D213Gfs*10 | Frame Shift Ins (INS) | VAF 14/35 reads (40%) | called by mutect2, varscan2
- AKAP11 | c.654T>G p.A218= | Silent (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- DSCAM | c.3243C>T p.T1081= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs746296406; called by muse, mutect2, varscan2
- IGHV3-20 | chr14:106210935 GTC>TGGTCAAA | Silent (INS) | VAF 35/69 reads (51%) | called by pindel, varscan2*
- MLH3 | c.177T>C p.F59= | Silent (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- TTN | c.23838A>G p.P7946= (on ENST00000591111; = p.P7019= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/118 reads (52%) | called by muse, mutect2, varscan2
- ZNF256 | c.267C>T p.T89= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs755800325; called by muse, mutect2, varscan2
- AC116366.2 | c.-389dup | 5'UTR (INS) | VAF 12/93 reads (13%) | catalogued as rs760051116; called by mutect2, pindel, varscan2
- AJUBA | c.*15T>C | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- ASB7 | c.817+43T>C | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.-63G>A | 5'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- NRXN1 | c.833-32750T>C | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- REG1B | c.183+61G>T | Intron (SNP) | VAF 20/37 reads (54%) | catalogued as rs533079813; called by muse, mutect2, varscan2
- RP1 | c.*66C>A | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
